Gene-level copy-number profile of tumor specimen TCGA-85-8582-01A from TCGA case TCGA-85-8582, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 49.7 years (18,168 days).
Specimen TCGA-85-8582-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.c6b4f98e-0a08-431a-aefa-c2f4f05d87fb.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-8582-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 394 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d42006d6-2096-46dc-a3c0-23193852ab13

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 2,409; copy number 2: 45,187; copy number 3: 12,244; copy number 4: 126; copy number 5: 229; copy number 6: 33.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-8582-01A-21D-2391-01): tumor purity 0.21, ploidy 2.59, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,601,086, 1 gene: LCE3C.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 262 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 6 (within-gene range 2–6): AC244205.1.
- chr2:88,857,161–89,046,466, 20 genes, copy number 6: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13.
- chr11:19,350,724–20,121,601, 1 gene, copy number 6 (within-gene range 2–6): NAV2.
- chr11:19,710,934–20,383,782, 8 genes, copy number 6: AC009549.1, MIR4694, NAV2-AS3, NAV2-AS2, NAV2-AS1, AC068860.1, DBX1, HTATIP2.
- chr11:66,435,075–67,317,431, 40 genes, copy number 5 (within-gene range 2–5): MRPL11, AP002748.3, PELI3, AP002748.4, DPP3, AP002748.5, BBS1, AP002748.6, ZDHHC24, ACTN3, AP002748.2, CTSF, CCDC87, CCS, RNU4-39P, RBM14, RBM14-RBM4, RBM4, RBM4B, SPTBN2, RN7SL12P, C11orf80, C1QBPP2, FTLP6, RCE1, PC, LRFN4, RNU7-23P, MIR3163, C11orf86, SYT12, MIR6860, RHOD, KDM2A, AP001885.1, AP001885.3, GRK2, ANKRD13D, SSH3, AP001885.2.
- chr14:105,764,503–106,377,733, 106 genes, copy number 5 (broad region; genes not listed).
- chr16:14,301,389–14,331,067, 1 gene, copy number 5 (within-gene range 2–5): MIR193BHG.
- chr16:14,309,285–15,734,691, 54 genes, copy number 5 (within-gene range 2–5): MIR365A, LINC02130, AC040173.1, PARN, RN7SL274P, BFAR, RNU7-125P, PLA2G10, AC009167.1, NPIPA3, AC136443.1, AC136443.4, NPIPA2, AC136443.2, ABCC6P2, NOMO1, AC136443.5, AC136443.3, MIR3179-1, MIR3670-1, AC138932.1, MIR3180-1, PKD1P3, Y_RNA, NPIPA1, MIR6511A1, MIR6770-1, AC138932.3, PDXDC1, AC138932.2, MIR1972-1, AC138932.4, NTAN1, RRN3, AC139256.1, NPIPP1, PKD1P6-NPIPP1, PKD1P6, MIR6511B2, Y_RNA, MIR3180-4, AC126763.1, AC137803.1, NPIPA5, MPV17L, AC140504.1, BMERB1, MARF1, AC026401.1, MIR6506, NDE1, MIR484, AC026401.2, AC026401.3.
- chr16:24,537,693–24,827,632, 3 genes, copy number 6 (within-gene range 4–6): RBBP6, TNRC6A, LINC01567.
- chr18:29,518,259–29,650,440, 2 genes, copy number 5: AC117569.1, AC117569.2.
- chr18:31,937,533–32,470,882, 20 genes, copy number 5: RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2, GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2, HNRNPA1P7.
- chr18:32,511,663–32,582,828, 3 genes, copy number 5: WBP11P1, AC009835.1, AC025887.1.
- chr19:30,228,290–30,713,538, 3 genes, copy number 5 (within-gene range 3–5): ZNF536, AC011504.1, AC011478.1.

Autosomal genes at a single copy (total copy number 1): 22. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
